MMRF case MMRF_1856 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/74329eda-5808-47cf-a5b5-7a85b99f5e7a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 54 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 55.0 years (20,072 days); ISS stage: II; Days to last known disease status: 1,092 days (3.0 years); Days to last follow up: 1,092 days (3.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 138 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 188 days; Days to treatment end: 188 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 253 days; Days to treatment end: 335 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 340 days; Days to treatment end: 432 days (1.2 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,092.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -7 (ECOG 1): M Protein 6.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.3 mg/dL; Beta 2 Microglobulin 4.09 µg/mL; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 129 µmol/L; Calcium 2.26 mmol/L; Albumin 39 g/L; Total Protein 12.5 g/dL; Glucose 5.9 mmol/L.
- Day 88 (ECOG 1): M Protein 4.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.93 mg/dL; Beta 2 Microglobulin 3.99 µg/mL; Lactate Dehydrogenase 3.35 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 102 µmol/L; Blood Urea Nitrogen 6.8 mmol/L; Calcium 2.13 mmol/L; Albumin 39 g/L; Total Protein 10.2 g/dL.
- Day 148 (ECOG 1): M Protein 3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.3 mg/dL; Beta 2 Microglobulin 4.22 µg/mL; Lactate Dehydrogenase 2.9 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 230 ×10⁹/L; Creatinine 123 µmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 9.6 g/dL; Glucose 5.8 mmol/L.
- Day 253 (ECOG 1): M Protein 1.3 g/dL; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 9.8 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 87 µmol/L; Blood Urea Nitrogen 4.8 mmol/L; Calcium 2.51 mmol/L; Albumin 46 g/L; Total Protein 8.8 g/dL; Glucose 7.2 mmol/L.
- Day 361 (ECOG 1): M Protein 6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.35 mg/dL; Immunoglobulin G 80.1 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 2.49 µg/mL; Hemoglobin 7.01 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 111 ×10⁹/L; Creatinine 81 µmol/L; Calcium 2.34 mmol/L; Albumin 42 g/L; Total Protein 6.9 g/dL.
- Day 445: M Protein 5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.09 mg/dL; Beta 2 Microglobulin 2.28 µg/mL; Hemoglobin 7.19 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 119 ×10⁹/L; Creatinine 82 µmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.9 g/dL.
- Day 559: M Protein 5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.82 mg/dL; Beta 2 Microglobulin 1.76 µg/mL; Hemoglobin 7.44 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 112 ×10⁹/L; Creatinine 89 µmol/L; Calcium 2.3 mmol/L; Albumin 45 g/L; Total Protein 7.3 g/dL.
- Day 644: M Protein 5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.66 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.63 mg/dL; Beta 2 Microglobulin 2.31 µg/mL; Lactate Dehydrogenase 2.28 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 103 ×10⁹/L; Creatinine 91 µmol/L; Blood Urea Nitrogen 5.9 mmol/L; Calcium 2.29 mmol/L; Albumin 46 g/L; Total Protein 7.4 g/dL; Glucose 4.9 mmol/L.
- Day 728: M Protein 4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.57 mg/dL; Beta 2 Microglobulin 2.19 µg/mL; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 0.5 ×10⁹/L; Platelets 74 ×10⁹/L; Creatinine 97 µmol/L; Blood Urea Nitrogen 5.4 mmol/L; Calcium 2.12 mmol/L; Albumin 37 g/L; Total Protein 6.8 g/dL; Glucose 6.6 mmol/L.
- Day 819: M Protein 4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.45 mg/dL; Beta 2 Microglobulin 1.99 µg/mL; Lactate Dehydrogenase 3.12 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 97 ×10⁹/L; Creatinine 90 µmol/L; Blood Urea Nitrogen 6.2 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 7 g/dL; Glucose 6.2 mmol/L.

Other clinical attributes
- Day -7: Weight: 87 kg; Height: 174 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1856_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -7 days.
- Sample MMRF_1856_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -7 days.
